Surgical pathology report (de-identified scan), TCGA case TCGA-EL-A3T6, project TCGA-THCA (Thyroid Carcinoma), tissue source site MD Anderson, specimen TCGA-EL-A3T6-01A (Primary Tumor).

Pathology Report

Pathology,

DOB:
Physician

Sex:

Collected:

Received:

Case type: Surgical Case

Accession

DIAGNOSIS

(A) TOTAL THYROIDECTOMY:

PAPILLARY THYROID CARCINOMA (4.5 CM).
TUMOR CONFINED WITHIN THYROID TISSUE.
No extracapsular extension identified.
Unremarkable parathyroid tissue, no tumor present.
One lymph node, no tumor present.

Entire report and diagnosis completed by:

*ICD-O-3
carcinoma, papillary,
thyroid
8260/3
Site: thyroid, NOS
4-3-12
RP*

GROSS DESCRIPTION

(A) TOTAL THYROIDECTOMY - A total thyroidectomy with overall measurements, 8.0 x 5.0 x 3.5 cm. The right lobe appears unremarkable and measures 4.0 x 3.0 x 1.0 cm and mostly appears fibrotic. The left lobe measures 6.0 x 5.0 x 3.5 cm and contains well-defined friable light tan and soft mass measuring 4.5 x 4.0 x 3.0 cm. The tumor abuts the external surface and the capsule of the lobe. No gross involvement of the surgical margin, but tumor is noted. The tumor also appears friable and papillary in nature. The specimen is submitted entirely in A1-A5, sequential sectioning of the right lobe from superior to inferior; A5, A6, isthmus; A8-A22, sequential sectioning of the left lobe from superior inferior including tumor and adjacent soft tissue.

CLINICAL HISTORY

History of papillary thyroid cancer.

SNOMED CODES

T-B6000, M-80503

Released by:

Source: NCI Genomic Data Commons file ff80ddd6-899a-435f-9ec3-386b0406d419 (TCGA-EL-A3T6.146DAFAC-42A9-4AFB-805A-6E970520D880.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).